Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A49X, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A49X-01A (Primary Tumor).

[page 1 of 5]
Tel:

Fax:

Clinical Case Report **(For Collection of Cancerous Tissue)**

ICD-0-3

Carcinoma, Squamous cell, NOS 8070/3
Site: esophagus, middle third C15.4

10/2/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status		Race
		☐ Single ☒ Married ☐ Divorced ☐ Widow		VIETNAMESE
Gender	Weight			Blood Pressure
☒ Male ☐ Female				Heart Rate

HISTORY OF PRESENT ILLNESS
Chief Complaints: Trouble Swallowing, cough, fever
Symptoms: Weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses		# of Pregnancies
	Date of Last Menses		# of Live Births
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA							
Test	Result		Date	Test	Result		Date
HIV	☒ Negative	☐ Positive: _____		CEA	☐ Negative	☐ Positive: _____	
Hep B	☒ Negative	☐ Positive: _____		CA 15-3	☐ Negative	☐ Positive: _____	
Hep C	☒ Negative	☐ Positive: _____		CA 19-9	☐ Negative	☐ Positive: _____	
AFP	☐ Negative	☐ Positive: _____		PSA	☐ Negative	☐ Positive: _____	
Other:	☐ Negative	☐ Positive: _____		Other:	☐ Negative	☐ Positive: _____	
B/T Cell Markers:							

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy	Carcinoma	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T3 N0 M0 Stage: II A		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of the esophagus			
Primary Tumor			
Organ	Detailed Location	Size	
Subcarinal esophageal tumor	middle	3 x 2 x 1 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T3 N0 M0 Stage: II A			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
oesophageal Tumours	3 x 2 x 1 cm	middle	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N 0 M 0		Stage: IIA	
Notes:			

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION				STRUCTURAL PATTERN			
	+	-			+	-	
Diffuse		☒		Streaming			
Mosaic	☒			Storiform			
Necrosis		☒		Fibrosis			
Lymphocytic Infiltration	☒			Palisading			
Vascular Invasion		☒		Cystic Degeneration			
Clusterized	☒			Bleeding			
Alveolar Formation		☒		Myxoid Change			
Indian File		☒		Pseudomoma/Calcification			

2. Cellular features:

Squamous		Adenomatous		Sarcomatous		Lymphomatous	
	+	-		+	-		+
Squamous Cell	☒		Glandular cell			Large Cell	
Spindle Cell	☒		Cell Stratification			Small Cell	
Keratin	☒		Secretion			RS Cell/RS Like	
Desmosome	☒		Intracyt. Vacuole			Inflam. Cell	
Pearl	☒		Gland formation			Plasma Cell	
Otherwise Specified: D1 60% D2 60% D3 40% D4 40%							

2. Cellular Differentiation:

Well	Moderately	Poor
	☒	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			☒	
Hyperchromatism			☒	
Nucleolar Prominent			☒	
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	
Nuclear Grade			☒	

Histological Diagnosis: Squamous cell carcinoma, G2

Comments: _____

Date: _____

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

IHP/A Discrepancy		☒
Case is (re)classified	☒	☐
Reviewed/Initiated	☒	☐

Source: NCI Genomic Data Commons file fa72282a-098e-41bc-aef7-94b34241dcf9 (TCGA-LN-A49X.77C11ABB-33FB-4038-AE20-ECE2831EE6AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).